Somatic mutation profile of tumor specimen TCGA-AG-3878-01A (aliquot TCGA-AG-3878-01A-02W-0899-10) from TCGA case TCGA-AG-3878, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 64.4 years (23,527 days).
Specimen TCGA-AG-3878-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af9cf4c3-844d-42c5-8bed-9551c1be9087.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3878-10A (Blood Derived Normal), aliquot TCGA-AG-3878-10A-01W-0901-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a05825c-beb2-413f-b856-2a282929972e

The open-access MAF lists 97 somatic variants for this specimen: 81 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 14, Nonsense Mutation 14, Frame Shift Del 3, Frame Shift Ins 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1787C>G p.S596* | Nonsense Mutation (SNP) | VAF 65/439 reads (15%) | catalogued as rs1554083134, CM056295, COSV57348561, COSV57392461; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3982C>T p.Q1328* | Nonsense Mutation (SNP) | VAF 63/190 reads (33%) | hotspot (GDC flag); catalogued as rs398123121, CM930028, COSV57324976; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 29/157 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 39/183 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADH1A | c.119A>T p.K40M | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52924694; called by muse, mutect2, varscan2
- AP1AR | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 158/542 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as rs754855886, COSV56768814; called by muse, varscan2
- ARID1A | c.2167C>T p.Q723* | Nonsense Mutation (SNP) | VAF 30/145 reads (21%) | catalogued as COSV61374103; called by muse, mutect2, varscan2
- C1orf43 | c.535T>A p.Y179N (on ENST00000368521 / NM_001297718.2; = p.Y145N on NM_015449.4) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV62966116; called by muse, mutect2, varscan2
- CCNH | c.643_646del p.T215Pfs*21 | Frame Shift Del (DEL) | VAF 54/338 reads (16%) | catalogued as rs1307794299; called by mutect2, pindel, varscan2
- CDH5 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs764490337, COSV58516610; called by muse, mutect2, varscan2
- CDH8 | c.1568A>G p.D523G | Missense Mutation (SNP) | VAF 26/698 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100184707; called by muse, mutect2
- CEP135 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 106/758 reads (14%) | catalogued as rs760955800, COSV57258905; called by muse, mutect2, varscan2
- CHD1L | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 110/700 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1379475915, COSV63614488; called by muse, varscan2
- CRYBG3 | c.7464C>G p.H2488Q | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV51711092; called by muse, mutect2
- CSMD1 | c.9226G>A p.A3076T (on ENST00000520002; = p.A3075T on NM_033225.6) | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs755172128, COSV59308281; called by muse, mutect2, varscan2
- CSPP1 | c.2824A>G p.K942E (on ENST00000676605; = p.K901E on NM_024790.6) | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as rs757668617, COSV51582895; called by mutect2, varscan2
- DCAF1 | c.4094A>G p.Y1365C | Missense Mutation (SNP) | VAF 82/453 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs782657004, COSV100245084; called by muse, mutect2, varscan2
- DCT | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100986331; called by muse, mutect2
- DMXL1 | c.1391A>C p.N464T | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100225298; called by muse, mutect2, varscan2
- DMXL2 | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 34/260 reads (13%) | catalogued as COSV99199012; called by muse, mutect2, varscan2
- DYNC1H1 | c.3419C>T p.T1140M | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs587780331, COSV64136058; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF2B5 | c.1940C>G p.A647G (on ENST00000647909; = p.A639G on NM_003907.3) | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99889621; called by muse, mutect2, varscan2
- ENAM | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs143134915; called by muse, mutect2, varscan2
- FAM181A | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs149056402; called by muse, mutect2
- FAT4 | c.13543G>A p.A4515T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs369929089; called by muse, mutect2, varscan2
- FBXW10 | c.2641C>T p.R881* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as rs147519900; called by mutect2, varscan2
- FGD5 | c.2461G>A p.V821M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206631746, COSV53240320; called by muse, mutect2, varscan2
- FLT1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 74/858 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs758936491, COSV56724980, COSV56736012; called by muse, mutect2
- GABRB2 | c.1077G>T p.K359N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.201); catalogued as COSV50907256; called by muse, mutect2, varscan2
- HIBCH | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 53/360 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569593420, COSV62891289; called by muse, mutect2, varscan2
- HLCS | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1166869596, COSV60792671; called by muse, mutect2, varscan2
- HMCN1 | c.12300T>G p.C4100W | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54892201; called by muse, mutect2, varscan2
- HRC | c.423C>A p.D141E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99418531; called by muse, mutect2, varscan2
- HSPA13 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 28/185 reads (15%) | catalogued as COSV53465034; called by muse, mutect2, varscan2
- INA | c.1097G>T p.R366M | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100878724; called by muse, mutect2
- KCNH5 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 90/469 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100528559, COSV59770942; called by muse, mutect2, varscan2
- KLC1 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 69/186 reads (37%) | catalogued as COSV55806739; called by muse, mutect2, varscan2
- KRT74 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs569075312, COSV99977737; called by muse, mutect2, varscan2
- KRT84 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs113837792; called by muse, mutect2, varscan2
- LMAN1 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 130/860 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826550; called by muse, varscan2
- LRP6 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 92/781 reads (12%) | catalogued as rs1211813119, COSV99742863; called by muse, varscan2
- LRRC7 | c.4434G>A p.M1478I (on ENST00000651989 / NM_001370785.2; = p.M1398I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV99230684; called by muse, mutect2
- MC4R | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as rs749768113, CM003757, COSV55351798; called by mutect2, varscan2
- MEAK7 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV100640464; called by muse, mutect2, varscan2
- MS4A14 | c.971C>A p.A324D | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV55734263; called by muse, mutect2, varscan2
- MUC16 | c.4679C>A p.A1560E | Missense Mutation (SNP) | VAF 62/2406 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV101202310; called by muse, mutect2
- MYH14 | c.2363G>A p.R788Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs779829368, COSV99224569; called by muse, mutect2
- MYLK | c.4603G>A p.V1535I | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.648); catalogued as rs776503378, COSV60605693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBEA | c.6238C>T p.R2080* | Nonsense Mutation (SNP) | VAF 92/471 reads (20%) | catalogued as COSV59773827; called by muse, mutect2, varscan2
- NIPAL2 | c.753G>T p.M251I | Missense Mutation (SNP) | VAF 184/534 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV57839330; called by muse, mutect2, varscan2
- NKG7 | c.260del p.P87Qfs*63 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs765087839; called by mutect2, varscan2
- NRG3 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs564020344, COSV64551383; called by muse, mutect2, varscan2
- NTM | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs951593215, COSV66177489; called by muse, mutect2, varscan2
- OR14C36 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 24/201 reads (12%) | catalogued as rs1231791456, COSV58602646; called by muse, mutect2, varscan2
- OR4L1 | c.920G>T p.S307I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV59849471; called by muse, mutect2, varscan2
- OR9A4 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 115/625 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs540557231, COSV71885855; called by muse, mutect2, varscan2
- OTOGL | c.5570A>G p.Q1857R (on ENST00000547103; = p.Q1848R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV54015587; called by muse, mutect2, varscan2
- PABPC4 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 111/610 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.834); catalogued as rs749537752, COSV63293339; called by muse, mutect2, varscan2
- PGBD1 | c.1877T>G p.F626C | Missense Mutation (SNP) | VAF 55/352 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV52552575; called by muse, mutect2, varscan2
- PHKG2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as rs535265672, COSV100079903; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIOK2 | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 78/394 reads (20%) | catalogued as COSV51612296; called by muse, mutect2, varscan2
- SCAF11 | c.4279A>G p.T1427A | Missense Mutation (SNP) | VAF 69/522 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV65475983; called by muse, mutect2, varscan2
- SEC24B | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1451292223, COSV99494573; called by muse, mutect2, varscan2
- SIN3B | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs369206489; called by muse, mutect2, varscan2
- SPATA31D1 | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 90/824 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV61192780, COSV61194642; called by muse, mutect2, varscan2
- SRGAP1 | c.299G>A p.W100* | Nonsense Mutation (SNP) | VAF 46/340 reads (14%) | catalogued as COSV61896588; called by muse, mutect2, varscan2
- SULF2 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs533810544, COSV59074960; called by muse, mutect2, varscan2
- TBC1D9 | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV71307258; called by muse, mutect2
- TMEM131L | c.4772C>T p.A1591V | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs199553865, COSV53643112; called by muse, mutect2, varscan2
- TMEM216 | c.217C>A p.R73S (on ENST00000515837 / NM_001173990.3; = p.R12S on NM_016499.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/562 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM121486, COSV100609944, COSV58425974; called by muse, mutect2
- TRNAU1AP | c.221C>A p.T74K | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as COSV65777734; called by muse, mutect2, varscan2
- TXLNG | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 10/334 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101200621; called by muse, mutect2
- UTRN | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV100840785; called by muse, mutect2, varscan2
- ZFHX3 | c.5321C>A p.P1774H | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99215459; called by muse, mutect2, varscan2
- ZKSCAN1 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV60873619; called by muse, mutect2, varscan2
- ZNF638 | c.5885A>G p.K1962R | Missense Mutation (SNP) | VAF 123/599 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV52491091; called by muse, mutect2, varscan2
- BCOR | c.2389_2390del p.V797Cfs*19 | Frame Shift Del (DEL) | VAF 27/49 reads (55%) | called by mutect2, varscan2
- BTBD11 | c.2255C>T p.A752V (on ENST00000280758 / NM_001018072.2; = p.A289V on NM_001017523.2) | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2
- DCBLD2 | c.1681dup p.T561Nfs*2 | Frame Shift Ins (INS) | VAF 48/260 reads (18%) | called by mutect2, varscan2
- TGIF1 | c.187dup p.C63Lfs*2 (on ENST00000330513 / NM_001374396.1; = p.C83Lfs*2 on NM_003244.4) | Frame Shift Ins (INS) | VAF 45/115 reads (39%) | called by mutect2, pindel, varscan2
- ZNF197 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- BEND5 | c.792C>T p.P264= | Silent (SNP) | VAF 40/284 reads (14%) | catalogued as rs377372975, COSV65718651; called by muse, mutect2, varscan2
- BRINP1 | c.999C>A p.G333= | Silent (SNP) | VAF 58/336 reads (17%) | catalogued as rs758663814, COSV56297259; called by muse, mutect2, varscan2
- CP | c.3129C>T p.T1043= | Silent (SNP) | VAF 114/569 reads (20%) | catalogued as rs746317601, COSV52830040; called by muse, mutect2, varscan2
- CRISPLD1 | c.816G>A p.R272= | Silent (SNP) | VAF 22/180 reads (12%) | catalogued as COSV51544011; called by muse, mutect2, varscan2
- DAGLB | c.336C>T p.A112= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as rs771315806, COSV51703308; called by muse, mutect2, varscan2
- DCP2 | c.1251C>A p.I417= | Silent (SNP) | VAF 12/356 reads (3%) | catalogued as COSV101203980; called by muse, mutect2
- LYAR | c.108C>T p.C36= | Silent (SNP) | VAF 28/202 reads (14%) | catalogued as rs528236112, COSV58642583; called by muse, mutect2, varscan2
- MAMDC2 | c.63G>T p.L21= | Silent (SNP) | VAF 160/780 reads (21%) | catalogued as COSV65857605; called by muse, mutect2, varscan2
- NPAP1 | c.522C>T p.D174= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs368120585, COSV100274980; called by muse, mutect2, varscan2
- STRBP | c.1284A>C p.T428= | Silent (SNP) | VAF 28/267 reads (10%) | catalogued as COSV62117663; called by muse, mutect2, varscan2
- TET2 | c.2391C>T p.F797= | Silent (SNP) | VAF 29/192 reads (15%) | catalogued as rs144220888; called by muse, mutect2, varscan2
- TLX1 | c.612G>A p.P204= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1178108091, COSV64622343; called by muse, mutect2, varscan2
- UBR4 | c.3429T>A p.A1143= | Silent (SNP) | VAF 54/343 reads (16%) | catalogued as COSV64386863; called by muse, mutect2, varscan2
- USP48 | c.2862G>A p.T954= | Silent (SNP) | VAF 92/457 reads (20%) | catalogued as rs1012844489, COSV57608964; called by muse, mutect2, varscan2
- ANK1 | c.-2G>T | 5'UTR (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99227386; called by muse, mutect2, varscan2
- RBM44 | c.-98-2134T>C | Intron (SNP) | VAF 13/97 reads (13%) | catalogued as COSV57628705; called by muse, mutect2, varscan2
